Somatic mutation profile of tumor specimen 0DLV3M from CCDI case PBBZSZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.4 years (1,230 days).
Specimen 0DLV3M: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4a8a9528-0e46-4f78-82fd-8782ee2db6b8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLV2Y (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a9152ad9-00af-4e00-a2a5-dff7ba94e594

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 6, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRIP1 | c.2329C>T p.R777C | Missense Mutation (SNP) | VAF 644/1642 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768555161, COSV51998004; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C5orf52 | c.433G>A p.V145M | Missense Mutation (SNP) | VAF 594/1472 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs777631429; called by muse, mutect2, varscan2
- KRT6B | c.1243C>T p.R415C | Missense Mutation (SNP) | VAF 989/2875 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); catalogued as rs556860047, COSV52883214; called by muse, mutect2
- OR10G4 | c.694G>A p.G232R | Missense Mutation (SNP) | VAF 681/1613 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57978376; called by muse, mutect2, varscan2
- THEMIS | c.1768G>A p.V590I | Missense Mutation (SNP) | VAF 678/1498 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs555567289, COSV100965499; called by muse, mutect2, varscan2
- VEZT | c.260A>G p.D87G | Missense Mutation (SNP) | VAF 309/820 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.1698G>A p.S566= | Silent (SNP) | VAF 244/581 reads (42%) | catalogued as rs1045685871; called by muse, mutect2, varscan2
- KRT33B | c.1116C>T p.C372= | Silent (SNP) | VAF 193/584 reads (33%) | catalogued as rs139682874, COSV52442512; called by muse, mutect2, varscan2
- TFE3 | c.894G>A p.V298= | Silent (SNP) | VAF 506/627 reads (81%) | called by muse, mutect2, varscan2
